Surgical pathology report (de-identified scan), TCGA case TCGA-KM-8441, project TCGA-KICH (Kidney Chromophobe), tissue source site NCI Urologic Oncology Branch, specimen TCGA-KM-8441-01A (Primary Tumor).

[page 1 of 4]
DIAGNOSIS:

- 1. Kidney, right, tumor #1, partial nephrectomy: Renal cell carcinoma, chromophobe type.
- 2. Kidney, right, tumor #2, partial nephrectomy: Renal cell carcinoma, chromophobe type.
- 3. Kidney, right, tumor #3, partial nephrectomy: Renal cell carcinoma, chromophobe type. Chromophomatosis.
- 4. Kidney, right, tumor #4, partial nephrectomy: Renal cell carcinoma, chromophobe type.
- 5. Kidney, right, tumor #5, partial nephrectomy: Renal cell carcinoma, chromophobe type.
- 6. Kidney, right, tumor #6, partial nephrectomy: Renal cell carcinoma, chromophobe type. Chromophomatosis
- 7. Kidney, right, tumor #7, partial nephrectomy: Renal cell carcinoma, chromophobe type.
- 8. Kidney, right, tumor #8, partial nephrectomy: Renal cell carcinoma, chromophobe type. Chromophomatosis.
- 9. Kidney, right, tumor #9, partial nephrectomy: Renal cell carcinoma, chromophobe type.
- 10. Kidney, right, tumor #10, partial nephrectomy: Renal cell carcinoma, chromophobe type. Chromophomatosis.

Patient Identification

[page 2 of 4]
[REDACTED]

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION: Brief Clinical History: history of multifocal RCC, suspected Birt hogg dube but prelim genetic testing negative. Family history of pneumothorax. Patient with left radical nephrectomy previously. now with 10 tumors\,br\,br\attenti [REDACTED]

PROCEDURE: Operative Findings: right renal masses x 10 Post-Operative Diagnosis: Same Pre-Operative Diagnosis: right renal masses x 10, possible Birt hogg dube

SPECIMENS SUBMITTED: 1. TUMOR, Right kidney # 1
2. TUMOR, Right kidney # 2
3. TUMOR, Right kidney # 3
4. TUMOR, Right kidney # 4
5. TUMOR, Right kidney # 5
6. TUMOR, Right kidney # 6
7. TUMOR, Right kidney # 7
8. TUMOR, Right kidney # 8
9. TUMOR, Right kidney # 9
10. TUMOR, Right kidney # 10

GROSS DESCRIPTION: Received are 10 freshly submitted specimens, each in containers labeled with the patient's name, medical record number, medical record number, and further specified as follows:

1. "Right kidney tumor #1" are 2 focally hemorrhagic kidney fragments 5.7 and 6.4 cm in greatest dimensions each and in the aggregate 6.7 x 5.5 x 2.5 cm. Sectioning reveals focally variegated, maroon-tan cut surfaces. No tissues are procured. Gross photographs are taken. The entire specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. Representative cross-sections are submitted in white cassettes white cassettes

Patient Identification [REDACTED]

[page 3 of 4]
2. "Right kidney tumor #2" is tan-pink soft tissue fragment, 2.1 x 2.0 x 1.6 cm. It is bisected revealing a variegated, yellow-pink soft cut surface. Approximately 40% of tissue is procured for [REDACTED] Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassettes S

3. "Right kidney tumor #3" is a tan-pink nodular tissue fragment, 2.4 x 2 x 1.3 cm. It is bisected revealing a tan-pink soft homogeneous cut surface. Approximately 50% of tissue is procured for [REDACTED] Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassettes SI

4. "Right kidney tumor #4" is tan-pink, irregularly-shaped kidney fragment, 4.5 x 3.4 x 1.1 cm. No tissues are procured. The specimen is entirely placed into formalin and submitted to Pathology. Gross photographs are taken. In Surgical Pathology, the specimen matches the above description. The specimen is serially sectioned and entirely submitted in white cassettes

5. "Right kidney tumor #5" is an intact spherical tan-pink nodule, 2 x 2 x 1.5 cm. There is a focal rim of normal-appearing parenchyma. It is bisected revealing a tan-pink smooth cut surface with minimal focal hemorrhage. Approximately 50% of tissue from the nodule to include normal is procured for [REDACTED] Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. It is serially sectioned and entirely submitted in white cassettes

6. "Right kidney tumor #6" is an intact spherical tan-pink nodule, 2 x 2 x 1.4 cm. It has a 2 x 0.4 x 0.4 cm attached adipose tissue. The nodule is bisected revealing a tan-pink soft smooth cut surface with minimal focal hemorrhage. Gross photographs are taken. Approximately 50% of the nodule is procured for [REDACTED] The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassettes 7-6C.

7. "Right kidney tumor #7" is an ovoid tan-pink partially encapsulated nodule, 4.9 x 4.3 x 4.3 cm with minimal attached perirenal fat. It is bisected revealing a red-tan variegated cut surface with minimal focal hemorrhage. Gross photographs are taken. Approximately 50% of tissue is procured for [REDACTED] The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is sectioned and represented in white cassettes

Patient Identification

[page 4 of 4]
[REDACTED]

8. "Right kidney tumor #8" is an ovoid tan-pink soft tissue fragment, 3 x 2.8 x 1.3 cm. It is bisected revealing a tan-pink and red hemorrhagic cut surface. Approximately 50% of tissue is procured for [REDACTED] B. Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is serially sectioned and entirely submitted in white cassettes [REDACTED] D.

9. "Right kidney tumor #9" is a spherical tan-pink nodule, 2.1 x 2 x 1.6 cm. It is bisected revealing a tan smooth soft cut surface with a well-circumscribed hemorrhagic maroon-red foci 1 cm in greatest dimensions. Approximately 50% of tissue is procured for [REDACTED]. Gross photographs are taken. The remainder of the specimen is serially sectioned and entirely submitted in white cassettes [REDACTED].

10. "Right kidney tumor #10" is a tan-pink nodule, 4.6 x 3.9 x 2.6 cm. It is bisected revealing a binodular tan-pink and red focally hemorrhagic cut surface. Approximately 40% of tissue is procured for [REDACTED]. Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. In Surgical Pathology, the specimen matches the above description. The remainder of the specimen is sectioned and entirely submitted in white cassettes SI

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

[REDACTED]

Patient Identification

Source: NCI Genomic Data Commons file 007e31de-db33-49c8-8e1c-5ff71e005ae1 (TCGA-KM-8441.BF0AD8A6-436D-4A8F-B89E-93F2D78FE9AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).